Somatic mutation profile of tumor specimen TCGA-CN-A6V6-01A (aliquot TCGA-CN-A6V6-01A-12D-A34J-08) from TCGA case TCGA-CN-A6V6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 59.7 years (21,811 days).
Specimen TCGA-CN-A6V6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0162dce4-2d0f-4188-b182-bc285792fbd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A6V6-10A (Blood Derived Normal), aliquot TCGA-CN-A6V6-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88575300-1a5a-4477-9503-3c9904627ab5

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, In Frame Del 2, Nonsense Mutation 2, 5'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCTF1 | c.4510G>A p.E1504K (on ENST00000366508; = p.E1478K on NM_015446.5) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100404269, COSV58248266; called by muse, mutect2, varscan2
- ALPK1 | c.3293G>A p.R1098K | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV99454994; called by muse, mutect2, varscan2
- AP3S2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs774639100, COSV60520094; called by muse, mutect2, varscan2
- APLP1 | c.476T>C p.L159S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV99384347; called by muse, mutect2, varscan2
- AR | c.2711T>C p.V904A | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101019147; called by muse, mutect2
- BCAN | c.2006G>T p.R669L | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as rs138466651, COSV100228392; called by muse, mutect2
- BCLAF3 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100503381; called by muse, mutect2, varscan2
- CACNA1C | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs786205746, COSV59742852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD9 | c.8318C>T p.S2773F (on ENST00000398510 / NM_001382353.1; = p.S2757F on NM_025134.7) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54609072, COSV99529607; called by muse, mutect2, varscan2
- CILP | c.2501A>G p.Q834R | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99973832; called by muse, mutect2, varscan2
- COL12A1 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.371); catalogued as COSV100486361; called by muse, mutect2
- CSMD2 | c.8587G>T p.A2863S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.3); catalogued as COSV99594106; called by muse, mutect2, varscan2
- CTDSPL | c.772G>A p.E258K (on ENST00000273179 / NM_001008392.2; = p.E247K on NM_005808.3) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56203505, COSV99828966; called by muse, mutect2, varscan2
- CTNND1 | c.1759T>C p.S587P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100650238; called by muse, mutect2, varscan2
- CYBB | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1556464560, COSV101059807; called by muse, mutect2, varscan2
- CYLC2 | c.17T>C p.F6S | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66337193; called by muse, mutect2, varscan2
- DDR2 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773580613, COSV63373756; called by muse, mutect2, varscan2
- DVL3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV100493765; called by muse, mutect2, varscan2
- EEA1 | c.3336+1G>A p.X1112_splice | Splice Site (SNP) | VAF 63/170 reads (37%) | catalogued as rs1227242288, COSV100468340; called by muse, mutect2, varscan2
- ENPP1 | c.1971A>T p.L657F | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100719627; called by muse, mutect2, varscan2
- EP300 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54325483, COSV54345374; called by muse, mutect2, varscan2
- FMO2 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99269300; called by muse, mutect2, varscan2
- FRMPD3 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as COSV99346903; called by muse, mutect2
- FSTL5 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs769789513, COSV100059906; called by muse, mutect2, varscan2
- GAL3ST4 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765947131, COSV100385616; called by muse, mutect2, varscan2
- HAS1 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1322739264, COSV99708566; called by muse, mutect2, varscan2
- HEATR1 | c.3680T>C p.V1227A | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100857771; called by muse, mutect2
- IKZF2 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100563791; called by muse, mutect2, varscan2
- IL6 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937615940, COSV99331534, COSV99331539; called by muse, mutect2, varscan2
- IRF4 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 100/148 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs908661692, COSV66706297; called by muse, mutect2, varscan2
- ITGA4 | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99276715; called by muse, mutect2, varscan2
- KIF23 | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs1477360558, COSV52978189; called by muse, mutect2, varscan2
- KMT2D | c.10481C>T p.P3494L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746854405, COSV99981436, COSV99985115; called by muse, mutect2, varscan2
- LHCGR | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99684100; called by muse, mutect2, varscan2
- LRP1B | c.9072G>C p.E3024D | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.675); catalogued as COSV101259691, COSV67273051; called by muse, mutect2, varscan2
- MAP2K2 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs202220799; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MKI67 | c.4822G>A p.D1608N | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs199755571, COSV64074741; called by muse, varscan2
- MKRN3 | c.1148A>G p.E383G | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100091513; called by muse, mutect2, varscan2
- MMRN2 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs200500870, COSV100813842; called by muse, mutect2, varscan2
- MPZ | c.346A>G p.N116D | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as CM016070, COSV100337951; called by muse, mutect2, varscan2
- NAF1 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as COSV99919327; called by muse, mutect2, varscan2
- PCCA | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100887020, COSV66188407; called by muse, mutect2, varscan2
- PCDH9 | c.3514A>G p.K1172E (on ENST00000377865 / NM_203487.3; = p.K1138E on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100122807; called by muse, mutect2, varscan2
- PCNX2 | c.5758G>A p.G1920R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs372629025; called by muse, mutect2, varscan2
- PLEKHG6 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99164840; called by muse, mutect2, varscan2
- PTPRK | c.2382G>A p.M794I (on ENST00000368215 / NM_001291984.2; = p.M795I on NM_002844.4) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as COSV100951450; called by muse, mutect2, varscan2
- RIC3 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100112292; called by muse, mutect2, varscan2
- RNF133 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV57373944; called by muse, mutect2
- RUFY2 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs775156393, COSV99769439; called by muse, mutect2, varscan2
- TBX3 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57474966, COSV99984042; called by muse, mutect2, varscan2
- WDR59 | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.193); catalogued as rs753117254, COSV50942658; called by muse, mutect2
- ZC4H2 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100565129; called by muse, mutect2, varscan2
- ZNF135 | c.1897C>A p.P633T (on ENST00000313434 / NM_001289401.2; = p.P645T on NM_003436.4) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536805; called by muse, mutect2
- CEACAM1 | c.1147dup p.I383Nfs*15 | Frame Shift Ins (INS) | VAF 37/179 reads (21%) | called by mutect2, pindel, varscan2
- LY6H | c.152_166del p.V51_R56delinsG | In Frame Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- MYH9 | c.4225_4227del p.D1409del | In Frame Del (DEL) | VAF 10/110 reads (9%) | called by mutect2, pindel
- TLK2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.586); called by muse, mutect2
- APBA3 | c.534G>A p.T178= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs948386996, COSV100349750; called by muse, mutect2, varscan2
- ATP13A4 | c.3477A>G p.A1159= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as COSV100710643; called by muse, mutect2, varscan2
- CCDC141 | c.2712C>T p.D904= | Silent (SNP) | VAF 73/270 reads (27%) | catalogued as rs142544322; called by muse, mutect2, varscan2
- CR1 | c.234C>T p.S78= | Silent (SNP) | VAF 28/221 reads (13%) | catalogued as rs142605009; called by muse, mutect2, varscan2
- CTNNA3 | c.1848A>G p.T616= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs182490263, COSV65615279, COSV65616366; called by muse, mutect2, varscan2
- DNM1 | c.1977G>C p.V659= | Silent (SNP) | VAF 25/304 reads (8%) | catalogued as COSV100360265; called by muse, mutect2
- FOXJ1 | c.294G>C p.R98= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV53948520, COSV99487316; called by muse, mutect2, varscan2
- IFT80 | c.255T>C p.S85= | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV100425068; called by muse, mutect2, varscan2
- ITGA8 | c.231G>A p.A77= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV100958816; called by muse, mutect2, varscan2
- MRPL51 | c.93G>A p.L31= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs753939070, COSV99975252; called by muse, mutect2, varscan2
- OR4L1 | c.432T>C p.F144= | Silent (SNP) | VAF 62/181 reads (34%) | catalogued as COSV100235865; called by muse, mutect2, varscan2
- RANBP2 | c.2145G>A p.R715= | Silent (SNP) | VAF 113/442 reads (26%) | catalogued as COSV99313001; called by muse, mutect2, varscan2
- RNF217 | c.1233C>T p.S411= (on ENST00000521654 / NM_001286398.2; = p.S119= on NM_152553.5) | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs758830005, COSV99255291; called by muse, mutect2, varscan2
- RSC1A1 | c.105T>G p.A35= | Silent (SNP) | VAF 58/308 reads (19%) | catalogued as COSV100197858; called by muse, mutect2, varscan2
- SLC9A3R1 | c.708C>T p.D236= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs387907536, COSV99380226; called by muse, varscan2
- SVOP | c.1104G>T p.L368= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100139598, COSV54469307; called by muse, mutect2, varscan2
- TPPP | c.414C>T p.R138= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs370221297; called by muse, mutect2, varscan2
- ZBTB38 | c.3075C>T p.L1025= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV100375942; called by muse, mutect2
- ZC3H12A | c.306C>G p.P102= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100897760; called by muse, mutect2, varscan2
- ZNF226 | c.1020T>C p.C340= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV100335227; called by muse, mutect2, varscan2
- ZNF229 | c.1647C>T p.C549= | Silent (SNP) | VAF 75/175 reads (43%) | catalogued as rs376063242; called by muse, mutect2, varscan2
- IMP4 | c.-1G>A | 5'UTR (SNP) | VAF 40/181 reads (22%) | catalogued as COSV99383832; called by muse, mutect2, varscan2
